Somatic mutation profile of tumor specimen C3N-03238-01 (aliquot CPT0193870006) from CPTAC case C3N-03238, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 47.6 years (17,380 days).
Specimen C3N-03238-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7543613d-c26f-4264-a262-3baedd8f50ea.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03238-71 (Blood Derived Normal), aliquot CPT0193990002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b08ce5f3-35e4-4b93-ba30-2484c6091af1

The open-access MAF lists 89 somatic variants for this specimen: 63 protein-altering or splice-affecting, 17 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 17, Nonsense Mutation 8, Intron 5, Splice Site 3, Frame Shift Del 3, Frame Shift Ins 2, 5'Flank 2, Translation Start Site 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 29/266 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- STK11 | c.580G>T p.D194Y | Missense Mutation (SNP) | VAF 11/97 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913315, CM991156, COSV58820621, COSV58820976, COSV99045288; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- CACHD1 | c.1160G>T p.G387V | Missense Mutation (SNP) | VAF 30/169 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV99263274; called by muse, mutect2, varscan2
- CCDC9 | c.1564C>T p.P522S | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as rs1255904211; called by muse, mutect2, varscan2
- CDKN2A | c.150+1G>A p.X50_splice | Splice Site (SNP) | VAF 8/186 reads (4%) | catalogued as COSV58682660, COSV58691878; called by muse, mutect2
- CYYR1 | c.85G>T p.A29S | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54836656, COSV54837080; called by muse, mutect2, varscan2
- FAM47B | c.916C>A p.H306N | Missense Mutation (SNP) | VAF 68/293 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.466); catalogued as COSV61453774; called by muse, mutect2, varscan2
- FMN2 | c.3296C>T p.P1099L | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.024); catalogued as rs370099468; called by muse, varscan2
- GDNF | c.526C>A p.Q176K | Missense Mutation (SNP) | VAF 39/406 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV58479849; called by muse, mutect2, varscan2
- HLCS | c.1246G>T p.G416C | Missense Mutation (SNP) | VAF 27/206 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.324); catalogued as rs756409633, COSV60797991; called by muse, mutect2, varscan2
- IGF2BP1 | c.1381G>T p.E461* | Nonsense Mutation (SNP) | VAF 18/109 reads (17%) | catalogued as COSV51736050; called by muse, mutect2, varscan2
- LRP5 | c.629A>G p.Y210C | Missense Mutation (SNP) | VAF 71/558 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770580929; called by muse, mutect2, varscan2
- LRRC55 | c.317G>T p.R106L | Missense Mutation (SNP) | VAF 49/395 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as COSV101546709; called by muse, mutect2, varscan2
- MYO1B | c.553A>G p.I185V | Missense Mutation (SNP) | VAF 25/201 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as rs1451328081; called by muse, mutect2, varscan2
- NPHS2 | c.874-2A>T p.X292_splice | Splice Site (SNP) | VAF 21/227 reads (9%) | catalogued as CS141355; called by muse, mutect2
- PKM | c.1223C>T p.P408L | Missense Mutation (SNP) | VAF 68/557 reads (12%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as rs148035865; called by muse, mutect2, varscan2
- PMEL | c.1925G>A p.R642H | Missense Mutation (SNP) | VAF 23/201 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs866948103, COSV59384936; called by muse, mutect2, varscan2
- SIGLEC1 | c.4199G>A p.G1400D | Missense Mutation (SNP) | VAF 36/366 reads (10%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.661); catalogued as rs776864717; called by muse, mutect2
- USP17L2 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 101/2086 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs968105535, COSV100414687; called by muse, mutect2
- ZFHX4 | c.6553C>T p.R2185* | Nonsense Mutation (SNP) | VAF 11/128 reads (9%) | catalogued as COSV51441550, COSV51500998; called by muse, mutect2
- ACSBG1 | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 33/198 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADAMTS5 | c.2666G>T p.R889M | Missense Mutation (SNP) | VAF 26/210 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRL4 | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.649); called by muse, mutect2
- ANKRD26 | c.3053A>C p.H1018P | Missense Mutation (SNP) | VAF 41/331 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- ARID1A | c.2281dup p.Q761Pfs*56 | Frame Shift Ins (INS) | VAF 13/90 reads (14%) | called by mutect2, pindel, varscan2
- BST1 | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by mutect2, varscan2
- CADPS2 | c.2304T>A p.F768L | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- CALB1 | c.299G>T p.C100F | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- CTNND2 | c.2701C>T p.L901F | Missense Mutation (SNP) | VAF 45/341 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DNAH2 | c.1583G>A p.R528H | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.037); called by muse, mutect2
- EMG1 | c.433A>G p.S145G | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, mutect2
- GCLC | c.440C>A p.S147* | Nonsense Mutation (SNP) | VAF 36/377 reads (10%) | called by muse, mutect2
- GDI2 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 18/183 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- IGHV4-34 | c.73del p.L25Cfs*14 | Frame Shift Del (DEL) | VAF 55/441 reads (12%) | called by mutect2, pindel, varscan2
- KCTD3 | c.1570G>T p.E524* | Nonsense Mutation (SNP) | VAF 33/168 reads (20%) | called by muse, mutect2, varscan2
- KCTD3 | c.1571A>T p.E524V | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- KEAP1 | c.286C>T p.H96Y | Missense Mutation (SNP) | VAF 31/284 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLHL1 | c.1675G>T p.G559* | Nonsense Mutation (SNP) | VAF 17/96 reads (18%) | called by muse, mutect2, varscan2
- LRP1 | c.9395A>T p.N3132I | Missense Mutation (SNP) | VAF 30/289 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LY75-CD302 | c.5034C>G p.Y1678* | Nonsense Mutation (SNP) | VAF 16/111 reads (14%) | called by muse, mutect2, varscan2
- MAP3K9 | c.1088del p.M363Rfs*41 | Frame Shift Del (DEL) | VAF 34/336 reads (10%) | called by mutect2, pindel
- MUC20 | c.1648G>T p.A550S | Missense Mutation (SNP) | VAF 34/509 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.042); called by muse, mutect2
- NALCN | c.2629C>T p.Q877* | Nonsense Mutation (SNP) | VAF 15/125 reads (12%) | called by muse, mutect2
- NALCN | c.1301T>A p.L434H | Missense Mutation (SNP) | VAF 57/388 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NBPF4 | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 35/370 reads (9%) | called by muse, mutect2, varscan2
- NT5C1B | c.53_54insT p.E20Rfs*12 | Frame Shift Ins (INS) | VAF 18/170 reads (11%) | called by mutect2, pindel
- OTOS | c.16G>T p.V6L | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- PDE3A | c.3410A>T p.Q1137L | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- PIWIL4 | c.455A>T p.N152I | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- PNPLA5 | c.1045A>G p.T349A | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- PPP3CC | c.1535C>T p.S512L | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by mutect2, varscan2
- RALGAPA1 | c.581T>G p.V194G | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- RUNDC3B | c.211del p.E71Nfs*4 | Frame Shift Del (DEL) | VAF 24/246 reads (10%) | called by mutect2, varscan2
- SLC30A6 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 36/244 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SPACA3 | c.532G>T p.V178F | Missense Mutation (SNP) | VAF 12/192 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- SPATA33 | c.248T>G p.V83G | Missense Mutation (SNP) | VAF 55/416 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- SPOCK3 | c.49A>C p.S17R | Missense Mutation (SNP) | VAF 28/316 reads (9%) | SIFT tolerated, low confidence (0.35); PolyPhen probably damaging (0.962); called by muse, mutect2
- TLE3 | c.131A>T p.K44I | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- TRIM32 | c.524A>C p.K175T | Missense Mutation (SNP) | VAF 64/435 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- UBR2 | c.1904C>G p.P635R | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.407); called by muse, mutect2
- USHBP1 | c.55-2A>G p.X19_splice | Splice Site (SNP) | VAF 16/138 reads (12%) | called by muse, mutect2, varscan2
- XIRP2 | c.88G>T p.D30Y | Missense Mutation (SNP) | VAF 32/215 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- ZC3H18 | c.2137G>T p.V713L | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- ACTR2 | c.687A>G p.Q229= | Silent (SNP) | VAF 18/138 reads (13%) | called by muse, mutect2, varscan2
- ALDH3B1 | c.1278C>T p.R426= | Silent (SNP) | VAF 45/357 reads (13%) | catalogued as rs1414469986; called by muse, mutect2, varscan2
- AUTS2 | c.2388G>T p.L796= | Silent (SNP) | VAF 50/428 reads (12%) | catalogued as rs1196691024; called by muse, mutect2, varscan2
- BIRC6 | c.13065C>T p.A4355= | Silent (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- CYP27B1 | c.1383A>G p.A461= | Silent (SNP) | VAF 45/403 reads (11%) | called by muse, mutect2, varscan2
- FLI1 | c.1284G>A p.G428= | Silent (SNP) | VAF 42/341 reads (12%) | called by muse, mutect2, varscan2
- LOXHD1 | c.1392C>T p.N464= | Silent (SNP) | VAF 37/224 reads (17%) | called by muse, mutect2, varscan2
- LOXL2 | c.27C>G p.L9= | Silent (SNP) | VAF 35/331 reads (11%) | called by muse, mutect2, varscan2
- MAP3K13 | c.1086C>T p.I362= | Silent (SNP) | VAF 24/230 reads (10%) | called by muse, mutect2, varscan2
- MICU1 | c.222G>T p.G74= | Silent (SNP) | VAF 5/92 reads (5%) | called by muse, mutect2
- NMNAT2 | c.642C>T p.N214= | Silent (SNP) | VAF 25/201 reads (12%) | catalogued as rs202243883; called by muse, mutect2, varscan2
- PLPP3 | c.501C>T p.S167= | Silent (SNP) | VAF 51/348 reads (15%) | called by muse, mutect2, varscan2
- RBM19 | c.18G>T p.V6= | Silent (SNP) | VAF 33/295 reads (11%) | called by muse, mutect2, varscan2
- SLC4A1 | c.1158C>A p.I386= | Silent (SNP) | VAF 48/339 reads (14%) | catalogued as rs375222701; called by muse, mutect2, varscan2
- SLC6A5 | c.1440T>G p.A480= | Silent (SNP) | VAF 74/582 reads (13%) | called by muse, mutect2, varscan2
- ST6GALNAC4 | c.900G>A p.R300= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs1313882709; called by mutect2, varscan2
- WDFY4 | c.9129G>A p.A3043= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as rs1043948661; called by muse, mutect2, varscan2
- CCR2 | c.941+21G>A | Intron (SNP) | VAF 29/319 reads (9%) | catalogued as rs773368456, COSV99432944; called by muse, mutect2
- CSMD3 | c.9863-48T>A | Intron (SNP) | VAF 15/173 reads (9%) | called by muse, mutect2
- FAM193A | chr4:2625280 C>G | 5'Flank (SNP) | VAF 20/181 reads (11%) | catalogued as COSV100218833; called by muse, mutect2, varscan2
- HGSNAT | c.564-1185G>C | Intron (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- LDAH | c.154+17G>A | Intron (SNP) | VAF 18/124 reads (15%) | catalogued as rs377328624; called by muse, mutect2, varscan2
- NRBP2 | c.1317+47C>T | Intron (SNP) | VAF 7/110 reads (6%) | catalogued as rs1473752471, COSV100589257; called by muse, mutect2
- NRXN1 | c.*10C>A | 3'UTR (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- NUP43 | c.-33C>T | 5'UTR (SNP) | VAF 87/630 reads (14%) | catalogued as rs759312715; called by muse, mutect2, varscan2
- TPCN1 | chr12:113221180 A>G | 5'Flank (SNP) | VAF 18/153 reads (12%) | called by muse, mutect2, varscan2
